Gene-level copy-number profile of tumor specimen TCGA-24-0982-01A from TCGA case TCGA-24-0982, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 77.2 years (28,201 days).
Specimen TCGA-24-0982-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.292ddf98-fc4e-4f92-8d5b-638de30cb924.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-0982-10C (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0dcb3f9c-b029-430d-bfaa-d6baeae283b0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,922; copy number 2: 27,300; copy number 3: 14,914; copy number 4: 10,611; copy number 5: 1,871; copy number 6: 1,425; copy number 7: 82; copy number 8: 293; copy number 9: 17; copy number 11: 299; copy number 12: 79.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-0982-01A-01D-0428-01): tumor purity 0.75, ploidy 2.86, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,066 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:171,314,183–173,791,887, 52 genes, copy number 5: FMO4, TOP1P1, SRP14P4, GM2AP2, CYCSP53, PRRC2C, MYOCOS, MYOC, PFN1P1, RPL4P3, VAMP4, Z98751.1, Z98751.3, Z98751.2, AL135931.1, EEF1AKNMT, AL031864.1, AL031864.2, DNM3, DNM3-IT1, DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1, RNU6-157P, PIGC, C1orf105, SUCO, RNU6-693P, FASLG, SLC25A38P1, Z98043.1, AL031599.1, AIMP1P2, Z97198.1, TNFSF18, GOT2P2, AL022310.1, TNFSF4, AL645568.2, AL645568.1, PRDX6-AS1, PRDX6, SLC9C2, AL139142.1, AL139142.2, ANKRD45, TEX50, KLHL20, BX248409.1, RN7SKP160.
- chr2:230,165,186–232,344,350, 65 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:159,711,852–161,253,532, 30 genes, copy number 5: AC092943.2, AC092943.1, IQCJ-SCHIP1-AS1, RNU2-31P, SCHIP1, IL12A-AS1, IL12A, LINC01100, BRD7P2, C3orf80, AC079594.1, IFT80, RPL35AP10, SMC4, MIR15B, MIR16-2, TRIM59, B3GAT3P1, RNU7-136P, KPNA4, SCARNA7, KRT8P12, RPL6P8, ARL14, SNORA72, AC069224.1, PPM1L, B3GALNT1, NMD3, AC108738.1.
- chr3:168,666,559–198,222,513, 594 genes, copy number 5–6 (broad region; genes not listed).
- chr5:58,198–53,110,063, 747 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr5:58,107,631–58,558,243, 8 genes, copy number 5: LINC02101, AC008786.1, PGAM1P1, PLK2, GAPT, AC008814.1, MIR548AE2, LINC02108.
- chr5:83,940,554–86,402,960, 24 genes, copy number 5–7 (within-gene range 3–7): EDIL3, RNU6-448P, EDIL3-DT, PPIAP79, AC114928.1, RBBP4P6, AC117522.3, AC117522.2, AC117522.1, AC010486.1, AC010486.2, AC010486.3, RPL5P17, AC026700.1, AC010595.1, RPS2P25, AC026414.1, PTP4A1P4, NBPF22P, AC020923.1, AC016550.1, AC016550.2, AC016550.3, AC026444.1.
- chr5:127,703,389–129,033,642, 10 genes, copy number 6 (within-gene range 4–6): CCDC192, CUL1P1, AC068658.1, LINC01184, SLC12A2, KDELC1P1, FBN2, Y_RNA, SLC27A6, AC008588.1.
- chr5:142,566,700–143,229,011, 9 genes, copy number 5: RPS12P10, FGF1, AC005592.1, LINC01844, AC005592.2, ARHGAP26, ARHGAP26-AS1, AC008533.1, ARHGAP26-IT1.
- chr5:143,332,605–143,333,239, 1 gene, copy number 5: RPL7P21.
- chr5:178,840,097–181,342,213, 113 genes, copy number 5 (broad region; genes not listed).
- chr6:6,725,036–7,541,338, 22 genes, copy number 5: AL031123.5, AL136361.1, BTF3P7, AL158817.1, RN7SL554P, AL139390.1, RREB1, AL355336.1, Y_RNA, AL589644.1, AL139095.5, SSR1, AL139095.4, CAGE1, AL139095.1, AL139095.2, AL139095.3, RIOK1, HNRNPLP1, AL138878.1, AL138878.2, AL031058.1.
- chr6:45,880,827–46,652,830, 10 genes, copy number 5 (within-gene range 4–5): CLIC5, RNU6-754P, AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2, AL359633.1, AL035670.1, CYP39A1.
- chr8:120,380,761–145,066,685, 455 genes, copy number 5–6 (broad region; genes not listed).
- chr12:30,086,342–34,249,958, 105 genes, copy number 5 (broad region; genes not listed).
- chr15:19,878,555–22,373,570, 130 genes, copy number 5 (broad region; genes not listed).
- chr18:24,426,634–24,453,531, 1 gene, copy number 12 (within-gene range 4–12): IMPACT.
- chr18:24,435,364–33,441,101, 125 genes, copy number 5–12 (within-gene range 4–12) (broad region; genes not listed).
- chr19:6,772,708–17,377,342, 592 genes, copy number 8–11 (broad region; genes not listed).
- chr19:18,929,201–19,203,414, 12 genes, copy number 12: HOMER3, HOMER3-AS1, RN7SL70P, SUGP2, ARMC6, SLC25A42, TMEM161A, MEF2B, BORCS8-MEF2B, BORCS8, RFXANK, NR2C2AP.
- chr19:28,435,388–30,085,893, 43 genes, copy number 5–9 (within-gene range 3–9): AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5.
- chr20:28,563,850–64,313,132, 918 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 501. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
